Somatic mutation profile of tumor specimen HCM-CSHL-0261-C50-86A (aliquot HCM-CSHL-0261-C50-86A-01D-A937-36) from HCMI case HCM-CSHL-0261-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 53.0 years (19,345 days).
Specimen HCM-CSHL-0261-C50-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efcd63ae-0954-44c4-a655-0f44307056ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0261-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0261-C50-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e9b3a22-9987-4b32-8f6d-1a06d742c2e4

The open-access MAF lists 67 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Frame Shift Del 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 109/255 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 52/170 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV50790179; called by muse, mutect2, varscan2
- ADAMTS5 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 293/600 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53178196; called by muse, mutect2, varscan2
- ATG2A | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 166/519 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs919227260; called by muse, mutect2, varscan2
- COL22A1 | c.4083C>G p.F1361L | Missense Mutation (SNP) | VAF 60/510 reads (12%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.992); catalogued as COSV57337305; called by muse, mutect2, varscan2
- DDI1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 150/450 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770274476, COSV56381028; called by muse, mutect2, varscan2
- EXD2 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1004874222; called by muse, mutect2
- F8 | c.2163G>T p.M721I | Missense Mutation (SNP) | VAF 41/696 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM020122; called by muse, mutect2
- FAM214B | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 33/675 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV59717084; called by muse, mutect2
- IGKV1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 129/409 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764059454; called by muse, varscan2
- JADE3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 128/565 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99510179; called by muse, mutect2, varscan2
- KIAA1671 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1264243527; called by muse, mutect2, varscan2
- KRIT1 | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 33/440 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV100388782, COSV60667575; called by muse, mutect2
- LRRIQ4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/459 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs767280598, COSV61619396; called by muse, mutect2
- NEXMIF | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 42/918 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99281409; called by muse, mutect2
- OR52A1 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 196/300 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs575135458; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 168/426 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs777414532, COSV62784355; called by muse, mutect2, varscan2
- REM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 211/637 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52428766; called by muse, mutect2, varscan2
- RSPH1 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 173/374 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs914516787; called by muse, mutect2, varscan2
- SAP130 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1339566194; called by muse, mutect2, varscan2
- SEMA5A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs145947305; called by muse, mutect2, varscan2
- SH3TC1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 312/445 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs552621094, COSV55284475; called by muse, mutect2, varscan2
- SLC5A2 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 46/1034 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57893861; called by muse, mutect2
- TARBP1 | c.4675G>C p.E1559Q | Missense Mutation (SNP) | VAF 248/584 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50212981; called by muse, mutect2, varscan2
- UBR5 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV55279851; called by muse, mutect2, varscan2
- AC019117.3 | c.2379G>A p.M793I | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- ANTKMT | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 56/1445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- AP4M1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ASH1L | c.5324_5325del p.C1775* | Frame Shift Del (DEL) | VAF 211/537 reads (39%) | called by mutect2, pindel, varscan2
- FLRT2 | c.1693C>A p.H565N | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by mutect2, varscan2
- HMCN1 | c.12143C>A p.A4048D | Missense Mutation (SNP) | VAF 34/816 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.6463G>A p.E2155K | Missense Mutation (SNP) | VAF 39/866 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIT | c.2349del p.A784Pfs*30 | Frame Shift Del (DEL) | VAF 158/307 reads (51%) | called by mutect2, pindel, varscan2
- NGF | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 19/437 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); called by muse, mutect2
- PCDH7 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, varscan2
- PLEKHA5 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PROCR | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 27/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- RNPC3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 16/477 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.412); called by muse, mutect2
- SLC18A3 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 188/572 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9B1 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- SMIM19 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 157/372 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by mutect2, varscan2
- SRFBP1 | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- STRIP2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 130/795 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D4 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TEDDM1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 354/828 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TRIP6 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR74 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZC3H3 | c.653C>A p.T218K | Missense Mutation (SNP) | VAF 64/1234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ZGRF1 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.261T>C p.D87= | Silent (SNP) | VAF 42/714 reads (6%) | called by muse, mutect2
- ASCL1 | c.372C>T p.N124= | Silent (SNP) | VAF 178/360 reads (49%) | catalogued as COSV99902170; called by muse, mutect2, varscan2
- CGRRF1 | c.330T>G p.A110= | Silent (SNP) | VAF 130/471 reads (28%) | called by muse, mutect2, varscan2
- CTDSPL | c.195G>C p.V65= | Silent (SNP) | VAF 58/365 reads (16%) | called by muse, mutect2, varscan2
- DCHS1 | c.9228G>C p.L3076= | Silent (SNP) | VAF 24/509 reads (5%) | called by muse, mutect2
- FAM83H | c.1662G>A p.A554= | Silent (SNP) | VAF 70/1063 reads (7%) | catalogued as rs1390924637, COSV66354877; called by muse, mutect2
- FREM3 | c.2874C>T p.D958= | Silent (SNP) | VAF 216/298 reads (72%) | catalogued as rs900565176; called by muse, mutect2, varscan2
- GOLGA8F | c.423G>A p.Q141= (on ENST00000526619; = p.Q347= on NM_001350920.2) | Silent (SNP) | VAF 32/612 reads (5%) | called by muse, mutect2
- HDGFL1 | c.396G>A p.P132= | Silent (SNP) | VAF 194/819 reads (24%) | catalogued as rs745407874, COSV100014763; called by muse, mutect2, varscan2
- KLF7 | c.330C>T p.L110= | Silent (SNP) | VAF 33/515 reads (6%) | catalogued as rs1480815061; called by muse, mutect2
- NLRP4 | c.2967C>T p.I989= | Silent (SNP) | VAF 142/682 reads (21%) | called by muse, mutect2, varscan2
- POLR2H | c.441G>A p.K147= | Silent (SNP) | VAF 29/320 reads (9%) | called by muse, mutect2
- SLCO3A1 | c.735C>T p.F245= | Silent (SNP) | VAF 29/346 reads (8%) | called by muse, mutect2
- TLE2 | c.969C>T p.L323= | Silent (SNP) | VAF 40/406 reads (10%) | catalogued as COSV99504247; called by muse, mutect2
- ZSCAN5B | c.1356G>T p.G452= | Silent (SNP) | VAF 102/1583 reads (6%) | catalogued as COSV62000239; called by muse, mutect2
- AL132655.6 | chr20:58840524 G>T | 5'Flank (SNP) | VAF 41/616 reads (7%) | catalogued as COSV58334215; called by muse, mutect2
- BDNF | c.-21-15482T>C | Intron (SNP) | VAF 15/261 reads (6%) | called by muse, mutect2
